Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PY, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PY-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: OUTPATIENT
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

year old female with bilateral thyroid nodular and right FNA positive for papillary thyroid cancer.

Specimens Submitted:

- 1: Delphian node
- 2: Right paratracheal lymph node (fs)
- 3: Total thyroidectomy

DIAGNOSIS:

1. Delphian node:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1

2. Right paratracheal lymph node (fs):

Lymph Node Dissection:
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.3cm.
Size of the largest metastatic focus: 0.2 cm.
Extranodal extension is not identified

Comment: The tumor focus is noted only on the frozen control slide and not on the original frozen slide.

3. Total thyroidectomy:

Tumor Type:
Papillary carcinoma, classical type
with tall cell features

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 2.5 cm.

1CD-0-3

Path: carcinoma, papillary, thyroid 8360/3
CACF: carcinoma, papillary, tall cell variant 8344/3

Site: thyroid, NOS C73.9

JW
8/31/11

[page 2 of 3]
Tumor Encapsulation:
Partially surrounded

Blood Vessel Invasion:
No definite vascular invasion is noted

Extrathyroid Extension:
Invades:perithyroidal soft tissue

Surgical Margins:
Free of tumor

Tumor Multicentricity:
one papillary microcarcinoma is identified (0.6 cm) in in left lobe.

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia

Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

_____, M.D./
*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received in formalin, labeled "Delphian node" and consists of a single pink tan firm lymph node measuring 0.8 x 0.4 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

2). The specimen is received fresh, labeled "right paratracheal lymph node", and consists of a lymph node measuring 1 x 0.6 x 0.4 cm. The specimen is entirely frozen.

Summary of sections:
FSC - frozen section control

3). The specimen is received labeled, labeled "total thyroidectomy, suture marks right lobe" and consists of a thyroid weighing 27 g with attached fragment of skeletal muscle measuring 3.5 x 1.5 x 0.3 cm. The right lobe measures 4 x 2.5 x 0.9 cm, the left lobe measures 4.3 x 2.9 x 1 cm and the isthmus measures 2.5 x 2 x 0.9 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 2.5 x 1.5 x 1.2 cm well-defined light-brown nodule with papillary excrescences, occupying entirely the isthmus and located at the junction

[page 3 of 3]
between the isthmus and the lower pole of the right lobe (N1), and abutting the posterior and anterior thyroid capsule. Cut section through the right lobe reveals two other well-defined soft gelatinous nodules in the mid and superior pole, measuring respectively 0.6 cm (N2) and 0.7 cm (N3). Sections through the left lobe reveal three well-defined soft light-brown, fleshy to gelatinous nodules, in the lower pole (1 cm, N4), mid pole (0.7 cm, N5) and lower pole (0.4 cm, N6). Sections through the remaining tissue reveal unremarkable red tan and beefy thyroid parenchyma. Representative sections of the specimen (N1) submitted for TPS. The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

N1- nodule 1, right lobe, representative sections
N2- nodule 2, right lobe, entirely submitted
N3- nodule 3, right lobe, entirely submitted
N4- nodule 4, left lobe, entirely submitted
N5- nodule 5, left lobe, entirely submitted
N6- nodule 6, left lobe, entirely submitted
RL - right lobe
LL - left lobe
SM- skeletal muscle

Summary of Sections:

Part 1: Delphian node

Block	Sect. Site	PCs
1	LN	1

Part 2: Right paratracheal lymph node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Total thyroidectomy

Block	Sect. Site	PCs
1	LL	1
3	N1	3
1	N2	1
1	N3	1
1	N4	1
1	N5	1
1	N6	1
1	RL	1
1	SM	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

2. Frozen section diagnosis: Right paratracheal lymph node (fs): Benign
Permanent diagnosis: See final

Source: NCI Genomic Data Commons file 4f3e8eff-ccb2-4e76-913a-0b141865b175 (TCGA-DJ-A2PY.4EFD0576-046A-4F23-BA02-637B2E38EDFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).